Gene-level copy-number profile of tumor specimen ALCH-B4CV-TTP1-A from ALCHEMIST case ALCH-B4CV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.8 years (21,098 days).
Specimen ALCH-B4CV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd9e29f5-21af-47e6-a23b-4eec971317c6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4CV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/25414f72-a037-4bf4-be3d-6c62f516e551

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 562; copy number 1: 5,638; copy number 2: 49,670; copy number 3: 2,613; copy number 4: 174; copy number 5: 104; copy number 6: 24; copy number 7: 2; copy number 9: 92; copy number 14: 24; copy number 20: 1; copy number 26: 10.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,820,170–112,850,643, 1 gene (within-gene range 0–1): LINC01356.
- chr2:91,617,160–91,659,972, 1 gene (within-gene range 0–2): LSP1P4.
- chr2:231,559,903–231,560,364, 1 gene: RPL21P35.
- chr2:232,520,388–232,536,667, 2 genes: PRSS56, CHRND.
- chr2:233,205,199–233,205,479, 1 gene (within-gene range 0–2): RN7SL32P.
- chr3:75,521,803–75,542,929, 2 genes (within-gene range 0–2): SNRPCP10, RPS3AP15.
- chr4:49,561,479–49,589,529, 3 genes: SNX18P24, AC119751.4, SNX18P25.
- chr7:131,500,262–131,558,217, 2 genes: PODXL, AC008264.1.
- chr8:33,547,754–33,600,023, 3 genes: RNF122, RN7SL621P, DUSP26.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–2): BUD31P1.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr10:42,242,721–42,276,842, 1 gene: AL031601.2.
- chr13:27,960,918–27,969,315, 1 gene: CDX2.
- chr15:25,255,579–25,257,027, 1 gene (within-gene range 0–2): AC124303.1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:63,471,604–63,472,093, 1 gene: PPIAP55.
- chr19:7,382,834–7,472,484, 3 genes (within-gene range 0–1): AC008878.3, AC119396.2, ARHGEF18.
- chr19:9,019,344–9,115,763, 5 genes: BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1.
- chr19:24,098,425–24,163,425, 3 genes (within-gene range 0–1): BNIP3P40, AC073534.2, AC073534.1.
- chr20:31,421,436–31,429,180, 1 gene: DEFB122.
- chr22:18,004,270–18,007,308, 1 gene (within-gene range 0–1): AC016027.2.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,650,023–18,653,617, 1 gene: PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 257 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,010,719–180,989,774, 74 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:182,588,093–183,428,778, 17 genes, copy number 9: AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151.
- chr8:38,382,364–38,409,527, 2 genes, copy number 5: AC087623.2, LETM2.
- chr8:38,408,048–38,408,742, 1 gene, copy number 5: AC087623.3.
- chr8:143,816,344–143,840,973, 6 genes, copy number 5: PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2.
- chr9:136,658,856–136,672,678, 2 genes, copy number 7 (within-gene range 4–7): EGFL7, MIR126.
- chr9:136,738,167–136,748,453, 2 genes, copy number 6 (within-gene range 3–6): LCN10, AL355987.1.
- chr9:136,754,386–136,766,255, 2 genes, copy number 5–6: LCN8, LCN15.
- chr9:136,791,344–136,800,595, 2 genes, copy number 5 (within-gene range 2–5): TMEM141, AL355987.3.
- chr10:104,122,058–104,126,385, 1 gene, copy number 5: SFR1.
- chr11:68,460,731–70,436,584, 56 genes, copy number 6–26: PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:105,049,395–105,065,445, 1 gene, copy number 5: GPR132.
- chr19:1,009,648–1,021,628, 3 genes, copy number 5 (within-gene range 2–5): TMEM259, AC004528.2, RNU6-2.
- chr19:1,065,923–1,106,791, 3 genes, copy number 5: ARHGAP45, POLR2E, GPX4.
- chr21:14,108,813–19,900,043, 83 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:18,623,339–18,625,289, 1 gene, copy number 9: SUSD2P2.
- chr22:18,715,815–18,719,341, 1 gene, copy number 5: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 3,294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
